Gene-level copy-number profile of tumor specimen TCGA-AR-A0TP-01A from TCGA case TCGA-AR-A0TP, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 43.3 years (15,812 days).
Specimen TCGA-AR-A0TP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.17e54aa6-f5d6-437a-8345-d40805c86430.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TP-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8cc63156-d931-4981-8910-b9ce061fe513

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 15,542; copy number 2: 32,476; copy number 3: 7,660; copy number 4: 3,444; copy number 5: 584.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0TP-01A-11D-A087-01): tumor purity 0.93, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:64,745,095–66,751,139, 30 genes (within-gene range 0–1): RAVER2, JAK1, AL606517.2, AL606517.1, LINC01359, SLC2A3P2, AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1.
- chr5:76,075,531–76,708,132, 15 genes (within-gene range 0–1): SAP18P1, AC026774.2, AC026774.1, SV2C, RNA5SP186, AC113404.2, AC113404.3, HMGN2P4, PDCD5P2, AC113404.1, SNRPCP2, IQGAP2, AC112173.1, AC026725.1, F2RL2.
- chr6:162,568,379–162,569,728, 1 gene: KRT8P44.
- chr8:150,584–1,708,476, 25 genes (within-gene range 0–1): AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2.
- chr17:33,013,087–34,174,964, 1 gene (within-gene range 0–1): ASIC2.
- chr17:33,529,787–34,726,170, 32 genes: AA06, AC011824.3, AC011824.2, AC011824.1, AC024614.1, AC024614.2, AC024614.3, AC024614.4, AC024610.2, AC004147.4, AC024610.1, AC123769.1, TLK2P1, AC004147.1, AC004147.5, RNA5SP438, AC004147.3, AC004147.2, LINC01989, AC005549.1, CCL2, CCL7, CCL11, CCL8, AC011193.2, CCL13, CCL1, AC011193.1, C17orf102, TMEM132E, AC005691.1, AC005552.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 584 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,327,399–121,463,508, 63 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:167,591,392–168,075,843, 11 genes, copy number 5 (within-gene range 4–5): AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5.
- chr8:78,148,101–78,153,913, 1 gene, copy number 5: AC084706.1.
- chr8:118,620,498–128,564,679, 167 genes, copy number 5 (broad region; genes not listed).
- chr8:139,460,062–145,066,685, 210 genes, copy number 5 (broad region; genes not listed).
- chr14:21,846,537–22,829,820, 132 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,924. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
